Somatic mutation profile of tumor specimen TCGA-FU-A23L-01A (aliquot TCGA-FU-A23L-01A-11D-A16O-08) from TCGA case TCGA-FU-A23L, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA1; Tumor grade: G3; Age at diagnosis: 60.1 years (21,962 days).
Specimen TCGA-FU-A23L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43c46346-8c8b-43ed-b04a-6c49699a7241.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FU-A23L-10A (Blood Derived Normal), aliquot TCGA-FU-A23L-10A-01D-A16O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a450cd8d-0a80-4e53-a461-44074fd7c634

The open-access MAF lists 174 somatic variants for this specimen: 135 protein-altering or splice-affecting, 34 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 34, Nonsense Mutation 9, Frame Shift Del 3, Splice Site 3, Intron 3, RNA 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLDC | c.2839-1G>C p.X947_splice | Splice Site (SNP) | VAF 10/37 reads (27%) | catalogued as rs386833569, CS061291, COSV58686436; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCG8 | c.227C>T p.T76I | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV55397655; called by muse, mutect2, varscan2
- ADAMTS2 | c.3440C>A p.S1147Y | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.556); catalogued as COSV52391331; called by muse, mutect2, varscan2
- ADCY4 | c.3166C>T p.Q1056* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV60258346; called by muse, mutect2, varscan2
- ADCY9 | c.155C>G p.S52C | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53582859; called by muse, mutect2, varscan2
- AFF3 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV100419836, COSV57878789; called by muse, mutect2, varscan2
- ALCAM | c.1209G>C p.K403N | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.673); catalogued as COSV60256403; called by muse, mutect2, varscan2
- APBB2 | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55964976, COSV99924008; called by muse, mutect2, varscan2
- APC | c.3409G>C p.D1137H | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV57332839, COSV57390518; called by muse, mutect2
- AR | c.2066G>C p.G689A | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM980107, COSV65957213; called by muse, mutect2, varscan2
- ARID2 | c.595A>G p.I199V | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.202); catalogued as COSV57602211, COSV57611367; called by muse, mutect2, varscan2
- ARID4A | c.2281G>C p.E761Q | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs760395662, COSV62167158; called by muse, mutect2, varscan2
- ATAD5 | c.2319G>C p.L773F | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58980254; called by muse, mutect2, varscan2
- ATP11B | c.1877G>C p.R626T | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60034269; called by muse, mutect2
- ATXN1 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as COSV55234364; called by muse, mutect2, varscan2
- BPTF | c.7147C>T p.P2383S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.021); catalogued as COSV58830675; called by muse, mutect2, varscan2
- CABP1 | c.946A>G p.T316A (on ENST00000316803 / NM_001033677.1; = p.T113A on NM_004276.5) | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV56460870; called by muse, mutect2, varscan2
- CAPNS1 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53085509; called by muse, mutect2, varscan2
- CARMIL3 | c.950G>C p.R317P | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs909993517, COSV57728931; called by muse, varscan2
- COL24A1 | c.3014G>C p.G1005A | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65316384; called by muse, mutect2, varscan2
- COL6A3 | c.6322G>C p.E2108Q | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55089570, COSV55115114; called by muse, mutect2, varscan2
- COL6A3 | c.5734G>C p.E1912Q | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV55115128; called by muse, mutect2, varscan2
- DDHD1 | c.667G>C p.D223H (on ENST00000323669; = p.D420H on NM_030637.3) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100079427, COSV60363446; called by muse, mutect2, varscan2
- DENND2C | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs372971179; called by muse, mutect2, varscan2
- EPC1 | c.1151A>G p.Q384R | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs1564525611, COSV53930504; called by muse, mutect2
- EPHA8 | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV51308166; called by muse, mutect2, varscan2
- EQTN | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV66218499; called by muse, mutect2, varscan2
- F8 | c.6923C>A p.S2308Y | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.64); catalogued as COSV57706950; called by muse, mutect2, varscan2
- FAM209B | c.255G>C p.Q85H | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); catalogued as COSV64915776; called by muse, mutect2, varscan2
- FAT4 | c.9018A>T p.R3006S | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV58713943; called by muse, mutect2, varscan2
- FMN2 | c.609C>G p.I203M | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV60420965, COSV60459751; called by muse, mutect2
- FRAS1 | c.10501G>C p.E3501Q | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV53658136; called by muse, mutect2, varscan2
- GCDH | c.1171G>A p.G391R | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53368991; called by muse, mutect2, varscan2
- GCNT3 | c.1076C>G p.S359C | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV68532660; called by muse, mutect2, varscan2
- GIMAP8 | c.1069G>C p.E357Q | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.473); catalogued as COSV56234878; called by muse, mutect2
- GLG1 | c.1627G>C p.E543Q | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as COSV52676013; called by muse, varscan2
- GLG1 | c.1572G>A p.M524I | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); catalogued as COSV52676028; called by muse, varscan2
- H1-0 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50648962; called by muse, mutect2, varscan2
- HDAC9 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV67782810; called by muse, mutect2
- HOXA3 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as rs773785595, COSV57829493; called by muse, mutect2, varscan2
- HOXD10 | c.619G>T p.G207C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.311); catalogued as rs148563899, COSV50895006, COSV50896931; called by muse, mutect2, varscan2
- IMMP1L | c.195-1G>C p.X65_splice | Splice Site (SNP) | VAF 7/39 reads (18%) | catalogued as COSV53447221; called by muse, mutect2, varscan2
- INTS4 | c.1697C>T p.S566L | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); catalogued as COSV71093569; called by muse, mutect2, varscan2
- JAKMIP2 | c.1672G>C p.E558Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV54617575; called by muse, mutect2
- KCNIP1 | c.36C>G p.F12L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV66177428, COSV66184049; called by muse, mutect2, varscan2
- KCNJ8 | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53715406, COSV53718613; called by muse, mutect2, varscan2
- KRTAP1-3 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV60335481, COSV60336603; called by muse, mutect2, varscan2
- LIG4 | c.228A>C p.E76D | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.045); catalogued as COSV63598346; called by muse, mutect2, varscan2
- LINS1 | c.1696G>C p.D566H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV59081258; called by muse, mutect2, varscan2
- LPIN3 | c.1845C>A p.F615L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV60039221; called by muse, mutect2, varscan2
- LRP5 | c.2773C>T p.R925C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs369471051, CM101321; called by mutect2, varscan2
- MAGEC1 | c.1263G>C p.L421F | Missense Mutation (SNP) | VAF 46/254 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.86); catalogued as COSV53572056, COSV99596830; called by muse, varscan2
- MAGT1 | c.620G>T p.R207I (on ENST00000618282 / NM_001367916.1; = p.R239I on NM_032121.5) | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1557216031, COSV63783331, COSV63783376; called by muse, mutect2
- MBTPS1 | c.1477G>C p.E493Q | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.297); catalogued as COSV100597480, COSV58573096; called by muse, mutect2, varscan2
- MED12L | c.5447T>A p.L1816H | Missense Mutation (SNP) | VAF 52/364 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.608); catalogued as COSV56401304; called by muse, mutect2, varscan2
- METTL2B | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV52311587; called by muse, mutect2, varscan2
- MKI67 | c.7867A>T p.T2623S | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.953); catalogued as COSV64077671; called by muse, mutect2, varscan2
- MMP12 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100405009, COSV58261978; called by muse, mutect2, varscan2
- MMP27 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV52783312; called by muse, mutect2, varscan2
- MMRN1 | c.238A>C p.K80Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV53343896; called by muse, mutect2, varscan2
- MROH2B | c.1956A>G p.G652= | Splice Region (SNP) | VAF 7/44 reads (16%) | catalogued as COSV68190623; called by muse, mutect2, varscan2
- MYF6 | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57353882; called by muse, mutect2, varscan2
- MYH7B | c.1581G>C p.E527D | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53418294, COSV53426688; called by muse, mutect2, varscan2
- NKAIN1 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.69); catalogued as COSV55275879; called by muse, mutect2
- NOX1 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373860304, COSV54197239; called by muse, mutect2, varscan2
- NTN1 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV51487120; called by muse, mutect2, varscan2
- NTNG2 | c.204C>G p.F68L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.495); catalogued as COSV62369478; called by muse, mutect2
- NUDC | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV57671267; called by muse, mutect2, varscan2
- NYAP2 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55998477; called by muse, mutect2, varscan2
- OR11H6 | c.945G>A p.M315I | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV59643842; called by muse, mutect2, varscan2
- OR2D2 | c.899G>A p.R300K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as COSV55058567; called by muse, mutect2, varscan2
- OR51E1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.54); catalogued as rs575981363, COSV67809895; called by muse, mutect2, varscan2
- OR6B2 | c.378C>G p.I126M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53157131; called by muse, mutect2, varscan2
- OR8H2 | c.49G>T p.G17* | Nonsense Mutation (SNP) | VAF 44/132 reads (33%) | catalogued as rs747354046, COSV57946880, COSV57947982; called by muse, varscan2
- OTUD4 | c.3114A>T p.R1038S (on ENST00000447906 / NM_001366057.1; = p.R973S on NM_001102653.1) | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV71382392; called by muse, mutect2, varscan2
- PER2 | c.2838G>C p.Q946H | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as COSV54529005; called by muse, mutect2
- PEX5L | c.1612C>T p.Q538* | Nonsense Mutation (SNP) | VAF 10/302 reads (3%) | catalogued as COSV55860320; called by muse, mutect2
- PLAGL2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55789551, COSV55790236; called by muse, mutect2
- PLBD1 | c.1011G>C p.K337N | Missense Mutation (SNP) | VAF 22/235 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as COSV53697070; called by muse, mutect2
- PODXL2 | c.1176C>G p.I392M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV100686228, COSV61066758; called by muse, varscan2
- PPAT | c.183C>G p.F61L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV51707098; called by muse, mutect2, varscan2
- PPOX | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 25/95 reads (26%) | catalogued as COSV57091906; called by muse, mutect2, varscan2
- PPP2R1A | c.1190T>A p.I397N | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV59049434; called by muse, mutect2, varscan2
- PPP6R2 | c.2474C>G p.S825C (on ENST00000216061 / NM_001365836.1; = p.S791C on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as COSV53299926, COSV53300632; called by muse, mutect2, varscan2
- PREB | c.990C>G p.F330L | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs781265603, COSV53206086, COSV53207679, COSV99574564; called by muse, mutect2, varscan2
- PRKAG2 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as COSV55244266; called by muse, mutect2, varscan2
- PRKDC | c.7179G>C p.L2393F | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.019); catalogued as COSV58067106; called by muse, mutect2, varscan2
- PSEN1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as COSV56195812, COSV56197833; called by muse, mutect2, varscan2
- PTDSS2 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV57280418; called by muse, mutect2, varscan2
- PXDN | c.3943T>A p.C1315S | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs1294754683, COSV53248537; called by muse, mutect2, varscan2
- PYGM | c.650T>C p.V217A | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV51232309; called by muse, mutect2, varscan2
- RABGEF1 | c.577G>C p.E193Q (on ENST00000439720 / NM_001287061.2; = p.E180Q on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.365); catalogued as COSV53161481, COSV53165848; called by muse, mutect2
- RECQL5 | c.1001G>A p.W334* | Nonsense Mutation (SNP) | VAF 21/137 reads (15%) | catalogued as COSV58642026; called by muse, mutect2, varscan2
- RGS17 | c.580C>G p.Q194E | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as COSV52812270; called by muse, mutect2, varscan2
- ROCK2 | c.3940C>T p.P1314S | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59967118; called by muse, mutect2, varscan2
- SEC24D | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV54879907; called by muse, mutect2, varscan2
- SEMA3A | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs755489133, COSV54876356, COSV54892507; called by mutect2, varscan2
- SEMA4A | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61774439; called by muse, mutect2, varscan2
- SF3B2 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.243); catalogued as COSV59430570; called by muse, mutect2
- SGO2 | c.704-1G>C p.X235_splice | Splice Site (SNP) | VAF 3/43 reads (7%) | catalogued as COSV63418704; called by muse, mutect2
- SIGLEC1 | c.2271G>C p.E757D | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV52462484, COSV52465332, COSV52475228; called by muse, mutect2
- SIGLEC10 | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV100218854, COSV59487633; called by muse, mutect2, varscan2
- SLC26A8 | c.1757A>T p.K586I | Missense Mutation (SNP) | VAF 110/154 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as rs867659983, COSV62888120; called by muse, mutect2, varscan2
- SLC29A4 | c.1293C>G p.F431L | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.216); catalogued as COSV51877496; called by muse, mutect2, varscan2
- SON | c.3163G>A p.E1055K | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV51672692; called by muse, mutect2, varscan2
- SPIDR | c.1822C>T p.H608Y | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.372); catalogued as COSV52393857; called by muse, mutect2, varscan2
- SUV39H2 | c.1148A>T p.D383V (on ENST00000354919 / NM_001193424.2; = p.D323V on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV57955952; called by muse, mutect2, varscan2
- TBATA | c.74C>A p.S25* | Nonsense Mutation (SNP) | VAF 27/66 reads (41%) | catalogued as COSV54722285; called by muse, mutect2, varscan2
- TEKT5 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 40/281 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51592315; called by muse, mutect2, varscan2
- THRAP3 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1030579095, COSV63567332; called by muse, mutect2, varscan2
- TMC2 | c.2028G>A p.M676I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62657742; called by muse, mutect2, varscan2
- TMEM120B | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs560432972, COSV61183887; called by muse, mutect2, varscan2
- TMEM51 | c.299T>C p.V100A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.053); catalogued as COSV65691604; called by muse, mutect2, varscan2
- TNIK | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.727); catalogued as rs756914989, COSV52674382; called by muse, mutect2
- TNRC6C | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV56954538; called by muse, mutect2, varscan2
- TRIP12 | c.554C>G p.S185* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV52274366; called by muse, mutect2, varscan2
- TTC17 | c.2009T>G p.L670R | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.33); PolyPhen probably damaging (1); catalogued as COSV50025399; called by muse, mutect2, varscan2
- TTN | c.12878C>T p.T4293I (on ENST00000591111; = p.T4247I on NM_003319.4) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | catalogued as COSV60417186; called by muse, mutect2, varscan2
- TTN | c.4991G>A p.R1664Q (on ENST00000591111; = p.R1618Q on NM_003319.4) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | PolyPhen benign (0.254); catalogued as rs375029799, COSV60109880, COSV60432843; called by muse, mutect2, varscan2
- TXNL4B | c.202G>C p.V68L | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV51701612; called by muse, mutect2, varscan2
- UMPS | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 49/309 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.096); catalogued as COSV51737045; called by muse, mutect2, varscan2
- WARS1 | c.585G>A p.M195I | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV59928052; called by muse, mutect2, varscan2
- YTHDC2 | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.662); catalogued as COSV50757555; called by muse, mutect2, varscan2
- ZC3H4 | c.668A>G p.E223G | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV53418066; called by muse, mutect2, varscan2
- ZEB2 | c.3280G>A p.E1094K | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV57953550, COSV57956836; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs754954301, COSV60159317; called by muse, mutect2, varscan2
- ZNF160 | c.13C>G p.Q5E | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV62000907, COSV62001388; called by muse, mutect2, varscan2
- ZNF594 | c.690G>C p.Q230H | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.66); catalogued as COSV68385207; called by muse, mutect2, varscan2
- ZNF652 | c.1261G>T p.D421Y | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62949088; called by muse, mutect2
- ZPLD1 | c.743G>C p.R248P (on ENST00000466937 / NM_001329788.1; = p.R264P on NM_175056.2) | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.977); catalogued as rs780790381, COSV60356346, COSV60356775; called by muse, mutect2, varscan2
- CD101 | c.1060_1061del p.K354Vfs*18 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | called by mutect2, pindel, varscan2
- IL17RA | c.1466A>G p.D489G | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- RPS6KA1 | c.1928_1929del p.T643Sfs*24 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | called by pindel, varscan2
- SPTLC2 | c.395_407del p.D132Gfs*31 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | called by mutect2, pindel, varscan2
- TRAV1-1 | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 15/115 reads (13%) | called by muse, mutect2
- AP002748.5 | c.708C>T p.V236= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV59151474, COSV59152697; called by muse, mutect2, varscan2
- BEST3 | c.756G>C p.L252= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV100437492, COSV58307062; called by muse, mutect2, varscan2
- CABS1 | c.966C>T p.D322= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV56734862; called by muse, mutect2, varscan2
- CCDC184 | c.174G>C p.V58= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV57252662; called by muse, mutect2, varscan2
- CDHR1 | c.906C>T p.I302= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV60567249; called by muse, mutect2, varscan2
- CUL4B | c.2137C>T p.L713= | Silent (SNP) | VAF 21/236 reads (9%) | called by muse, mutect2
- FNDC3B | c.1860G>A p.Q620= | Silent (SNP) | VAF 21/198 reads (11%) | catalogued as COSV61051488; called by muse, mutect2
- GABRB3 | c.246T>C p.Y82= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV54688257; called by muse, mutect2
- GALNT10 | c.651G>A p.L217= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as COSV51726422, COSV51735801; called by muse, mutect2, varscan2
- GPR19 | c.372C>G p.L124= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV60124920; called by muse, mutect2, varscan2
- KALRN | c.321C>T p.L107= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as rs748748909, COSV53783222; called by muse, mutect2, varscan2
- KANK1 | c.765G>A p.V255= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV63217035; called by muse, mutect2, varscan2
- KCNQ5 | c.870T>C p.D290= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV59687376; called by muse, mutect2, varscan2
- KMT2D | c.10566G>A p.Q3522= | Silent (SNP) | VAF 49/148 reads (33%) | catalogued as COSV56495186; called by muse, mutect2, varscan2
- LRIG3 | c.507C>G p.L169= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV57871297; called by muse, mutect2, varscan2
- LTBR | c.393C>T p.F131= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV57440104; called by muse, mutect2, varscan2
- LZTS1 | c.1790G>A p.*597= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV56118850; called by muse, mutect2, varscan2
- MAP4K2 | c.1719C>T p.P573= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs749227114, COSV53649777; called by muse, mutect2, varscan2
- MFSD8 | c.39C>G p.L13= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV56553321; called by muse, mutect2
- NALCN | c.2124C>T p.R708= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV51972174; called by muse, mutect2, varscan2
- NXF3 | c.1422C>A p.T474= | Silent (SNP) | VAF 61/229 reads (27%) | catalogued as COSV67705506; called by muse, mutect2, varscan2
- PCDHB5 | c.1587C>T p.R529= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as rs781920885, COSV50660007; called by muse, mutect2
- SIGLEC14 | c.597C>A p.T199= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV55784872; called by muse, varscan2
- SLC22A13 | c.891C>G p.V297= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV61292493; called by muse, mutect2, varscan2
- SMOX | c.1275C>T p.S425= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs200124130, COSV53864301; called by muse, mutect2, varscan2
- SNX29 | c.324C>T p.I108= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs1199624847, COSV73754507; called by muse, mutect2, varscan2
- SPOPL | c.207G>A p.L69= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV54511434, COSV54516230, COSV54516640; called by muse, mutect2, varscan2
- STK17B | c.735C>T p.L245= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV55827767; called by muse, mutect2, varscan2
- TENM2 | c.4764C>A p.P1588= (on ENST00000518659 / NM_001122679.2; = p.P1349= on NM_001080428.3) | Silent (SNP) | VAF 26/121 reads (21%) | catalogued as COSV69134244, COSV69144520; called by muse, mutect2, varscan2
- TP63 | c.987C>A p.T329= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV53223971; called by muse, mutect2, varscan2
- TRPC5 | c.1747T>C p.L583= | Silent (SNP) | VAF 34/395 reads (9%) | catalogued as COSV53305104; called by muse, mutect2
- USP31 | c.843C>G p.L281= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV54858664; called by mutect2, varscan2
- VIPAS39 | c.150C>T p.D50= | Silent (SNP) | VAF 94/288 reads (33%) | catalogued as rs566440125, COSV53631991; called by muse, mutect2, varscan2
- ZNF862 | c.1539G>A p.V513= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as COSV56226752; called by muse, mutect2, varscan2
- BIRC8 | n.1329C>A | RNA (SNP) | VAF 22/143 reads (15%) | catalogued as COSV70347301; called by muse, mutect2, varscan2
- FYB1 | c.1907+1657G>C | Intron (SNP) | VAF 64/96 reads (67%) | catalogued as rs1189366110, COSV60949100, COSV60950203; called by muse, mutect2, varscan2
- PLCE1 | c.1207-42898C>T | Intron (SNP) | VAF 33/144 reads (23%) | catalogued as COSV53376507; called by muse, mutect2, varscan2
- PTK2 | c.2030+2609C>T | Intron (SNP) | VAF 7/30 reads (23%) | catalogued as rs1351879603, COSV61794466; called by muse, mutect2, varscan2
- WASF4P | n.621G>C | RNA (SNP) | VAF 4/74 reads (5%) | called by muse, mutect2
